Somatic mutation profile of tumor specimen MBCProject_0540_T1_WES (aliquot MBCProject_0540_T1_WES_1) from CMI case MBCProject_0540, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.0 years (12,059 days).
Specimen MBCProject_0540_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b182a75-342c-4856-a45d-9542868a5051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0540_SALIVA (Saliva), aliquot MBCProject_0540_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78de3184-b933-4c28-b601-cbd9e3f4be15

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 2, Intron 2, Splice Site 1, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.044); catalogued as rs775861579, COSV55781203; called by muse, mutect2, varscan2
- ANKK1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746405597, COSV58273266, COSV58274845; called by muse, mutect2, varscan2
- CD4 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555117895, COSV50589823; called by muse, mutect2, varscan2
- DCAF4L2 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373178646; called by muse, mutect2, varscan2
- GDF7 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867444165, COSV55347273; called by muse, mutect2, varscan2
- GIMD1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs778559616; called by muse, mutect2
- KIRREL1 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 101/134 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs751139928; called by muse, mutect2, varscan2
- LIG3 | c.1270T>G p.S424A | Missense Mutation (SNP) | VAF 83/254 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1480667653; called by muse, mutect2, varscan2
- LRP12 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs777398485, COSV52633496; called by muse, mutect2
- P2RY1 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1376963549; called by muse, mutect2
- SPEN | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 51/123 reads (41%) | catalogued as COSV65361406; called by muse, mutect2, varscan2
- ST6GAL2 | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | PolyPhen probably damaging (0.998); catalogued as COSV100699647; called by muse, mutect2
- BBS12 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CEP89 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 46/146 reads (32%) | called by muse, mutect2, varscan2
- GLB1L3 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- HTR1A | c.1141T>A p.L381M | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IL31RA | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 96/268 reads (36%) | called by muse, varscan2
- MEN1 | c.516_519dup p.G174Pfs*12 | Frame Shift Ins (INS) | VAF 111/207 reads (54%) | called by mutect2, pindel, varscan2
- NVL | c.1632G>T p.E544D | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ROCK1 | c.3207A>C p.E1069D | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- SYNRG | c.3226C>A p.L1076I | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBX3 | c.1327_1331del p.S443Qfs*247 (on ENST00000257566 / NM_016569.4; = p.S423Qfs*247 on NM_005996.4) | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | called by mutect2, pindel, varscan2
- TRPA1 | c.2182C>T p.L728F | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CNTNAP3 | c.1974G>A p.A658= | Silent (SNP) | VAF 115/312 reads (37%) | catalogued as rs774300042, COSV52668500; called by muse, mutect2, varscan2
- DNAJB12 | c.87G>C p.P29= | Silent (SNP) | VAF 107/328 reads (33%) | called by muse, mutect2, varscan2
- KCNK5 | c.1251C>T p.D417= | Silent (SNP) | VAF 67/249 reads (27%) | catalogued as rs138652901; called by muse, mutect2, varscan2
- OR5B3 | c.699G>A p.Q233= | Silent (SNP) | VAF 200/328 reads (61%) | called by muse, mutect2, varscan2
- PDCD11 | c.4548G>A p.V1516= | Silent (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- SLC18A2 | c.1242C>T p.H414= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs760585747, COSV100041383; called by muse, mutect2
- SSX2IP | c.1545G>A p.P515= | Silent (SNP) | VAF 69/134 reads (51%) | catalogued as rs754121943; called by muse, mutect2, varscan2
- TMEM37 | c.246C>T p.P82= | Silent (SNP) | VAF 72/225 reads (32%) | catalogued as rs149498503; called by muse, mutect2, varscan2
- COX6A1P2 | n.77G>A | RNA (SNP) | VAF 38/580 reads (7%) | called by muse, mutect2
- DIO3 | chr14:101560370 C>T | 5'Flank (SNP) | VAF 8/64 reads (13%) | catalogued as rs1171992167; called by muse, mutect2, varscan2
- OBSCN | c.11660-2503G>A | Intron (SNP) | VAF 85/204 reads (42%) | called by muse, mutect2, varscan2
- PCM1 | c.1472+29G>T | Intron (SNP) | VAF 8/78 reads (10%) | catalogued as rs1280141766; called by muse, mutect2, varscan2
